Somatic mutation profile of tumor specimen TCGA-N5-A59F-01A (aliquot TCGA-N5-A59F-01A-11D-A28R-08) from TCGA case TCGA-N5-A59F, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Age at diagnosis: 65.2 years (23,826 days).
Specimen TCGA-N5-A59F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58d315fb-9531-4e3d-b0e8-26fc0a1844c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A59F-10A (Blood Derived Normal), aliquot TCGA-N5-A59F-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/904325de-0c85-4071-bd16-ca2ba3576309

The open-access MAF lists 51 somatic variants for this specimen: 44 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 5, Splice Site 1, 3'Flank 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 54/72 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs758968575; called by muse, mutect2, varscan2
- ASXL3 | c.5686C>A p.Q1896K | Missense Mutation (SNP) | VAF 31/498 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV52463600; called by muse, mutect2
- BRCA2 | c.5413A>G p.N1805D | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as rs1555284211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2B | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52805742; called by muse, mutect2, varscan2
- CSMD2 | c.3169G>A p.V1057M | Missense Mutation (SNP) | VAF 143/216 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141181841, COSV53958065; called by muse, mutect2, varscan2
- EGFLAM | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs776179036; called by muse, mutect2, varscan2
- ERBB3 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs142735651; called by muse, mutect2, varscan2
- FCRL2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs139872242; called by muse, mutect2, varscan2
- FOLR3 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs371010355; called by muse, mutect2, varscan2
- GATA3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1215707952, COSV60518835; called by muse, mutect2, varscan2
- GRM3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 169/209 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64472446, COSV64474804; called by muse, mutect2, varscan2
- HERC2 | c.5230C>T p.R1744* | Nonsense Mutation (SNP) | VAF 28/352 reads (8%) | catalogued as COSV55308761; called by muse, mutect2
- INSRR | c.2062T>C p.C688R | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751860063; called by muse, mutect2, varscan2
- MAGI2 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753587569; called by muse, mutect2, varscan2
- NPAP1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as rs746621095, COSV61507825, COSV61511976; called by muse, mutect2, varscan2
- OR2T27 | c.514C>G p.R172G | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV61283830; called by muse, mutect2, varscan2
- PCDHB10 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV53377257; called by muse, mutect2, varscan2
- SORBS3 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs761190844, COSV99531277; called by muse, mutect2, varscan2
- ZNF446 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs769334299; called by muse, varscan2
- ZP1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs138582317; called by muse, mutect2, varscan2
- ACRV1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- AGMO | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGRN | c.5051C>G p.T1684R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- AMY2B | c.1520C>A p.A507D | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- ARHGEF39 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPM | c.9491A>T p.Y3164F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CYP2A7 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- CYP4F3 | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FARP2 | c.867+4_867+7del p.X289_splice | Splice Site (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- GRIA1 | c.2072C>A p.A691E | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- HIGD1A | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ITGA11 | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MRPS7 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MS4A7 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.431); called by muse, mutect2
- PABPC5 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1B | c.451T>G p.S151A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RIF1 | c.2482T>C p.F828L | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTF1 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STK32C | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TENM2 | c.7770C>G p.S2590R (on ENST00000518659 / NM_001122679.2; = p.S2351R on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TSC22D1 | c.2150C>A p.P717Q | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- TSHZ3 | c.2215C>A p.P739T | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASAP2 | c.1929G>C p.G643= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- FLT4 | c.1941C>T p.H647= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs779623335, COSV56099825; called by muse, mutect2, varscan2
- GALNT17 | c.453G>A p.L151= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs1206181140; called by muse, mutect2
- PIGG | c.1944C>A p.G648= (on ENST00000453061 / NM_001127178.3; = p.G640= on NM_017733.4) | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- RPLP0 | c.213C>T p.N71= | Silent (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5752A>G | 3'UTR (SNP) | VAF 6/110 reads (5%) | catalogued as COSV57058072; called by muse, mutect2
- FANCD2 | chr3:10101219 A>G | 3'Flank (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
